Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7893, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7893-01A (Primary Tumor).

[page 1 of 2]
ORIGINAL REPORT

SPECIMEN:

- A. Distal pancreas - stitch marks neck of pancreas.
- B. Gallbladder.

CLINICAL HISTORY:

Pancreatic mass - body of the pancreas.

DIAGNOSIS:

A. DISTAL PANCREAS; RESECTION:

- INVASIVE POORLY DIFFERENTIATION DUCTAL ADENOCARCINOMA (7.0 cm)
INFILTRATING PANCREATIC PARENCHYMA AND EXTENDING INTO PERIPANCREATIC
FAT, PERINEURAL INVASION PRESENT, RADIAL RESECTION MARGIN POSITIVE FOR
MALIGNANCY, PROXIMAL AND DISTAL RESECTION MARGINS UNINVOLVED.
- HIGH GRADE PANCREATIC INTRAEPITHELIAL NEOPLASIA (PanIN III)
- EIGHT PERIPANCREATIC LYMPH NODES NEGATIVE FOR MALIGNANCY

B. GALLBLADDER; CHOLECYSTECTOMY:

- CHOLELITHIASIS, CHRONIC CHOLECYSTITIS, NEGATIVE FOR MALIGNANCY.

GROSS DESCRIPTION:

A. The specimen consists of distal pancreas which measures 12.0 x 4.5 x 3.0 cm. The proximal margin is marked by a long suture. The specimen is painted with silver nitrate. The body of the pancreas is almost completely occupied by a firm cylindrical tumor which measures 7.0 x 2.3 x 2.0 cm. The tumor appears to be confined within the pancreatic parenchyma and is 0.2 cm from the radial margin. The tumor is 2.0 cm from the proximal resection margin. The cut surfaces of the tumor are fairly circumscribed, yellow-white, predominantly solid with few small cystic areas near the periphery. The pancreatic duct appears to be intact in the tumor and is dilated. The duct measures 0.7 cm in diameter at the distal end of the pancreas. The proximal resection margin is painted with India ink.

FINAL

[page 2 of 2]
Chart ID:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Number:

GROSS DESCRIPTION:

Sections:

- A1. proximal resection margin
- A2-9. tumor
- A10. distal resection margin (enface)
- A11. tumor
- A12. one lymph node
- A13. two lymph nodes
- A14. additional section of the proximal margin
- A15-A16 tumor and radial margin
- A17 dilated duct

B. The specimen consists of a gallbladder which measures 10.5 x 2.3 x 2.0 cm. The outer surface is unremarkable. The wall measures less than 0.1 cm in thickness and the lumen contains numerous yellow-green stones admixed with dark green mucinous material. Sections are submitted in one cassette.

Co:

FINAL

Source: NCI Genomic Data Commons file 7de9e2d9-c48b-40d8-8d1e-8d395596a719 (TCGA-IB-7893.52E9B7DD-75DA-49C0-B8CE-B2CD33F01887.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).